TCGA case TCGA-A5-A0G1 — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Corpus uteri; Tissue source site: Cedars Sinai. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/53707bb3-426a-43cb-830f-3eeed930295f

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Dead; Days to death: 3,251 days (8.9 years).

Diagnoses (1)
1. Serous cystadenocarcinoma, NOS: ICD-O-3 morphology code: 8441/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 67.0 years (24,477 days); Year of diagnosis: 1996; Method of diagnosis: Biopsy; FIGO stage: Stage IA; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 0; Lymph nodes tested: 10.
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 0; Lymph nodes tested: 4.
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 10.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 72 days; Days to treatment end: 112 days; Treatment dose: 5,040 cGy; Course number: 1; Number of fractions: 28; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Surgery, Open; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.

Follow-up (1 entry)
- Days to follow up: 3,251 days (8.9 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 59 kg; Height: 168 cm; BMI: 20.9.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Former User; Hormonal replacement therapy status: Yes; Menopause status: Postmenopausal; Number of pregnancies: 3; Pregnancy outcome: Full Term Birth, NOS.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-A5-A0G1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 190 mg.
  Slide TCGA-A5-A0G1-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 10; Percent necrosis: 5; Percent stromal cells: 25; Percent lymphocyte infiltration: 90; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-A5-A0G1-01A-01-BS1: Section location: Bottom; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 10; Percent necrosis: 5; Percent stromal cells: 25; Percent lymphocyte infiltration: 90; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-A5-A0G1-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-A5-A0G1-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: Tumor free; Submitted tumor site: Endometrial; Histologic diagnosis: Serous endometrial adenocarcinoma; Method initial path diagnosis: Office Endometrial Biopsy; Surgical approach at diagnosis: open.
- Follow-up form: History menopausal hormone therapy: Yes, I have taken menopausal hormone therapy in the past, but no longer do; History tamoxifen use: Never Used; Hypertension diagnosis: No; Diabetes diagnosis indicator: No; Pregnancies full term count: 3; History colorectal cancer: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 3,251 days; disease-specific survival: no event (censored), 3,251 days; disease-free interval: no event (censored), 3,251 days; progression-free interval: no event (censored), 3,251 days.
